Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5790, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5790-01A (Primary Tumor).

CGA - CH - 5790

Diagnosis

1. Focally poorly differentiated, max. 1.9 cm, acinar adenocarcinoma of the prostate in both lobes with perineural growth along major nerves, focal infiltration of the periprostatic fatty connective tissue at several points and with tumor-free seminal vesicles and seminal ducts.
2. Two tumor-free lipomatous lymph nodes. No malignancy.

Remark

Extensive carcinoma infiltrates are found in the peripheral zone of both sides in all sections of the prostate. An infiltration of the periprostatic fatty connective tissue is found along major nerves in the right lateral region close to the apex and on the right close to the base. No identifiable invasion of the vessels. The left medial part of the apex shows foci of contact between the carcinoma and the blue labeling (diameter about 2 cm). In summary, the **tumor classification** is as follows: pT3a, pN0 (0/2), Gleason 3+4 = 7, Gleason 4: 30%, G3, L0, V0.

Source: NCI Genomic Data Commons file 2f65d699-b8e1-4e80-b36d-8699398bfe4e (TCGA-CH-5790.0F2F0A80-6A25-4374-96AD-0DBD6D136906.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).